Somatic mutation profile of tumor specimen TCGA-EU-5905-01A (aliquot TCGA-EU-5905-01A-11D-1669-08) from TCGA case TCGA-EU-5905, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.0 years (24,475 days).
Specimen TCGA-EU-5905-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50621425-a1b0-4d9a-b782-c7406d49e158.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EU-5905-10A (Blood Derived Normal), aliquot TCGA-EU-5905-10A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/903231e2-907c-48e0-a955-d4a0a9b784c2

The open-access MAF lists 63 somatic variants for this specimen: 53 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 9, Frame Shift Ins 4, Frame Shift Del 3, Nonsense Mutation 2, Splice Region 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS3 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54094725; called by muse, mutect2, varscan2
- ACTG1 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59510993; called by muse, mutect2, varscan2
- ACVR2B | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV61702723; called by muse, mutect2, varscan2
- BTBD8 | c.167T>G p.F56C | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as COSV61546877; called by muse, mutect2, varscan2
- CCNB3 | c.3169C>A p.P1057T | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV52075551; called by muse, mutect2, varscan2
- CFAP100 | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100729302, COSV61503533; called by muse, mutect2, varscan2
- CLC | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55685807; called by muse, mutect2
- CPNE3 | c.1395G>C p.E465D | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs763399183, COSV52207634; called by muse, mutect2, varscan2
- CUTA | c.464A>G p.Q155R (on ENST00000488034 / NM_001014840.2; = p.Q132R on NM_015921.3) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV53382973; called by muse, mutect2, varscan2
- DAND5 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.468); catalogued as COSV57684305; called by muse, mutect2, varscan2
- DDX4 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.051); catalogued as COSV61755759; called by muse, mutect2, varscan2
- ESAM | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54035593; called by muse, mutect2, varscan2
- FIGN | c.1833G>C p.M611I | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.104); catalogued as COSV60768723; called by muse, mutect2, varscan2
- GBP1 | c.415A>G p.M139V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs758061406, COSV65083880; called by muse, mutect2, varscan2
- GPSM1 | c.1663A>T p.I555F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52517869; called by muse, mutect2, varscan2
- INPP5F | c.1512G>C p.M504I | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62822138; called by muse, mutect2, varscan2
- INTS9 | c.1864G>C p.A622P | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV68434737; called by muse, mutect2, varscan2
- KAT14 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV66608226; called by muse, mutect2, varscan2
- KCNQ2 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs368720575; ClinVar: uncertain significance; called by muse, mutect2
- KCNQ3 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV66474292; called by muse, mutect2, varscan2
- KRT71 | c.1283A>T p.E428V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57291456; called by muse, mutect2, varscan2
- LRRC37A2 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV100238662; called by mutect2, varscan2
- LSM14B | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53381819; called by muse, mutect2, varscan2
- MCM3AP | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.103); catalogued as COSV52437423, COSV52445224; called by muse, mutect2, varscan2
- MSI1 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.821); catalogued as COSV57456779; called by muse, mutect2
- MYB | c.1025G>A p.S342N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57199328; called by muse, mutect2, varscan2
- MYO9B | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV68280468; called by muse, mutect2, varscan2
- PCDH1 | c.509C>A p.S170* | Nonsense Mutation (SNP) | VAF 63/410 reads (15%) | catalogued as COSV54615806; called by muse, mutect2, varscan2
- PCDH1 | c.508T>A p.S170T | Missense Mutation (SNP) | VAF 64/409 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV54615849; called by muse, mutect2, varscan2
- PDZD2 | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851429, COSV56862920; called by muse, mutect2, varscan2
- PHACTR4 | c.185C>A p.S62* (on ENST00000373839 / NM_001350159.2; = p.S72* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV65784426; called by muse, mutect2, varscan2
- PHLPP2 | c.3196A>G p.K1066E | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as COSV62425246; called by muse, mutect2, varscan2
- PRKAR1A | c.843G>C p.K281N | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV62235960; called by muse, mutect2, varscan2
- RYR1 | c.2110A>G p.N704D | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62101687; called by muse, mutect2, varscan2
- SGK1 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52811889; called by muse, mutect2, varscan2
- STAG1 | c.1314G>A p.K438= | Splice Region (SNP) | VAF 17/80 reads (21%) | catalogued as COSV52614503; called by muse, mutect2, varscan2
- TIAM1 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs753741491, COSV54559048; called by muse, mutect2, varscan2
- TINF2 | c.967G>C p.A323P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as rs755072937, COSV57469430, COSV57470493; called by muse, mutect2, varscan2
- TMEM203 | c.411G>T p.*137Yext*13 | Nonstop Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV58808132; called by muse, mutect2, varscan2
- UBR5 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs796264766, COSV55280964, COSV55291699; called by muse, mutect2, varscan2
- VGLL1 | c.717A>T p.K239N | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.178); catalogued as COSV65703451; called by muse, mutect2, varscan2
- ZMYM1 | c.2349A>T p.E783D | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63252366; called by muse, mutect2, varscan2
- ZNF423 | c.3086G>A p.R1029H (on ENST00000563137 / NM_001379286.1; = p.R1021H on NM_015069.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV52194863; called by muse, mutect2, varscan2
- ZNF518A | c.1902A>C p.Q634H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV60151972; called by muse, mutect2, varscan2
- ZNF646 | c.2571T>A p.F857L | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV54925181; called by muse, mutect2, varscan2
- CCT4 | c.718dup p.R240Kfs*3 | Frame Shift Ins (INS) | VAF 24/143 reads (17%) | called by mutect2, pindel, varscan2
- GNMT | c.222_226del p.M74Ifs*14 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- IGHA2 | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMOD3 | c.911dup p.N304Kfs*5 | Frame Shift Ins (INS) | VAF 64/142 reads (45%) | called by mutect2, pindel, varscan2
- MPHOSPH10 | c.1040del p.L347* | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | called by pindel, varscan2
- PKHD1 | c.5385dup p.A1797Gfs*9 | Frame Shift Ins (INS) | VAF 15/86 reads (17%) | called by mutect2, pindel
- PRUNE1 | c.30_33dup p.L12Cfs*15 | Frame Shift Ins (INS) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- VHL | c.404del p.L135Yfs*24 | Frame Shift Del (DEL) | VAF 81/182 reads (45%) | called by mutect2, pindel, varscan2
- ADAMTS4 | c.1041T>A p.I347= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV63488098; called by muse, mutect2, varscan2
- DPP9 | c.498C>T p.G166= (on ENST00000598800; = p.G195= on NM_139159.5) | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV53592248; called by muse, mutect2, varscan2
- FUS | c.1197T>C p.G399= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as COSV54218150; called by muse, mutect2, varscan2
- GALNT17 | c.1515C>A p.T505= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs571368084, COSV61169728; called by muse, mutect2, varscan2
- PAXBP1 | c.1824A>G p.K608= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as rs371129196; called by muse, mutect2, varscan2
- RAB32 | c.246C>T p.I82= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV62249294; called by muse, mutect2, varscan2
- SLCO4A1 | c.1911G>T p.V637= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV53889508, COSV53891927; called by muse, mutect2, varscan2
- TIAM1 | c.1167G>T p.R389= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV54559009; called by muse, mutect2, varscan2
- ZNF79 | c.372T>C p.S124= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV61071208; called by muse, mutect2, varscan2
- ASIC2 | c.556-179378dup | Intron (INS) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
